TCGA case TCGA-04-1351 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: Gynecologic Oncology Group. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/12b032ed-ff92-4bfe-b980-eb273ae8ae17

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 76 years; Vital status: Alive.

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Classification of tumor: primary; Age at diagnosis: 76.8 years (28,045 days); Year of diagnosis: 2004; Method of diagnosis: Incisional Biopsy; FIGO stage: Stage IIIC; Tumor grade: G2; Prior treatment: No; Days to last follow up: 1,991 days (5.5 years).
   Treatment given: Treatment type: Chemotherapy; Initial disease status: Recurrent Disease.
   Treatment given: Treatment type: Chemotherapy; Treatment intent type: Adjuvant.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 81.3 years (29,703 days); Days to diagnosis: 1,658 days (4.5 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease.

Follow-up (3 entries)
- Day 1,658 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 1,658 days (4.5 years); Evidence of recurrence type: Convincing Image Source.
- Days to follow up: 1,991 days (5.5 years); Disease response: Tumor Free.
- Karnofsky performance status: 100.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-04-1351-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 2; Intermediate dimension: 0.4; Shortest dimension: 0.2.
  Slide TCGA-04-1351-01A-01-TS1: Section location: Top; Percent tumor cells: 55; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 15; Percent stromal cells: 30.
  Slide TCGA-04-1351-01A-01-BS1: Section location: Bottom; Percent tumor cells: 40; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 20; Percent stromal cells: 40.
- Sample TCGA-04-1351-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1; Intermediate dimension: 1; Shortest dimension: 0.3.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: Tumor free; History neoadjuvant treatment: No.
- Follow-up form: Treatment outcome first course: Complete Remission/Response; Tumor status: Tumor free.

GDC annotations on this case (curator notes; quoted as recorded):
- Normal class but appears diseased on sample TCGA-04-1351-11A: Genomic data resembles tumor data.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,991 days; disease-specific survival: no event (censored), 1,991 days; disease-free interval: event (new tumor event after initially disease-free), 1,658 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 1,658 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-04-1351-01): tumor purity 0.72, ploidy 4.37, whole-genome doublings 2 (call status: legacy_call).
